Somatic mutation profile of tumor specimen C3N-03929-01 (aliquot CPT0219780006) from CPTAC case C3N-03929, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 51.0 years (18,638 days).
Specimen C3N-03929-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcc3390c-7a74-4a83-ab2d-192b759f5881.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03929-71 (Blood Derived Normal), aliquot CPT0220060002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f13a7181-da52-4585-9327-6b47b3e80420

The open-access MAF lists 343 somatic variants for this specimen: 222 protein-altering or splice-affecting, 74 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 194, Silent 74, Intron 22, Nonsense Mutation 10, 5'UTR 9, Frame Shift Del 6, 3'UTR 6, RNA 6, Splice Region 4, Splice Site 4, Frame Shift Ins 3, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 106/251 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 91/276 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACCS | c.626G>T p.R209L | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV55457017; called by muse, mutect2, varscan2
- ADGRA1 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.079); catalogued as rs199841510, COSV66925412; called by muse, mutect2, varscan2
- ADGRE5 | c.1611G>A p.M537I (on ENST00000242786 / NM_078481.4; = p.M444I on NM_001784.5) | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54393110; called by muse, mutect2, varscan2
- AP002748.5 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 50/612 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.322); catalogued as rs148576114; called by muse, mutect2
- ASB4 | c.992G>T p.C331F | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100367190, COSV57948905; called by muse, mutect2, varscan2
- BCHE | c.688G>T p.A230S | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as rs781532109; called by muse, mutect2, varscan2
- BRINP3 | c.860C>A p.P287Q | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66514208; called by muse, mutect2, varscan2
- C1orf94 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.608); catalogued as rs1445868579; called by muse, mutect2, varscan2
- CD226 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 111/262 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748967734, COSV99711430; called by muse, mutect2, varscan2
- CDK11A | c.1909A>G p.K637E (on ENST00000378633 / NM_001313896.2; = p.K634E on NM_024011.4) | Missense Mutation (SNP) | VAF 65/169 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs558644609; called by muse, mutect2, varscan2
- CIC | c.2894A>G p.Q965R | Missense Mutation (SNP) | VAF 131/545 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.351); catalogued as rs775842770; called by muse, mutect2, varscan2
- COL2A1 | c.1534C>T p.P512S | Missense Mutation (SNP) | VAF 203/446 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1444149100; called by muse, mutect2, varscan2
- CPED1 | c.2839C>A p.Q947K | Missense Mutation (SNP) | VAF 47/209 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV100120269; called by muse, mutect2, varscan2
- CYTH3 | c.670G>T p.G224C | Missense Mutation (SNP) | VAF 51/232 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63437551; called by muse, mutect2, varscan2
- DBX2 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.031); catalogued as rs866557013; called by muse, mutect2
- DDX55 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 23/320 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766244307; called by muse, mutect2
- EFCC1 | c.1670C>A p.P557H | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV101460042; called by muse, mutect2, varscan2
- FCRL4 | c.915G>A p.M305I | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV54861972, COSV54861986; called by muse, mutect2
- FPGT-TNNI3K | c.1503G>A p.M501I | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.771); catalogued as rs760873813; called by muse, mutect2, varscan2
- GABRD | c.1065C>A p.D355E | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.165); catalogued as COSV66080342; called by muse, mutect2, varscan2
- GRM6 | c.587C>G p.P196R | Missense Mutation (SNP) | VAF 99/294 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99179996; called by muse, mutect2, varscan2
- HTRA2 | c.1031G>A p.R344H | Missense Mutation (SNP) | VAF 60/497 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs201615648, COSV99239484; called by muse, mutect2, varscan2
- IFNAR1 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.744); catalogued as rs774610936, COSV54253986; called by muse, mutect2, varscan2
- KCNJ5 | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 35/555 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs1356200702, COSV100610797; called by muse, mutect2
- KDM3B | c.4934A>G p.D1645G | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58688274; called by muse, mutect2, varscan2
- KNL1 | c.601A>G p.T201A (on ENST00000346991 / NM_170589.5; = p.T175A on NM_144508.5) | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs1417221733, COSV61154556; called by muse, mutect2, varscan2
- LAMA1 | c.231A>G p.R77= | Splice Region (SNP) | VAF 49/230 reads (21%) | catalogued as rs775813971; called by muse, mutect2, varscan2
- LLGL2 | c.2254G>T p.A752S | Missense Mutation (SNP) | VAF 112/324 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.049); catalogued as rs764292060, COSV51349182; called by muse, mutect2, varscan2
- LPA | c.3875G>A p.G1292E | Missense Mutation (SNP) | VAF 122/418 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60312373; called by muse, mutect2, varscan2
- MAD1L1 | c.987G>T p.R329S | Missense Mutation (SNP) | VAF 76/310 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs778630947; called by muse, mutect2, varscan2
- MANSC1 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 77/136 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773610627; called by muse, mutect2, varscan2
- MAP2 | c.5107C>T p.H1703Y | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1478174826; called by muse, mutect2, varscan2
- MGAT5 | c.2180G>A p.R727Q | Missense Mutation (SNP) | VAF 23/404 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as rs754864583, COSV56096604; called by muse, mutect2
- MGST3 | c.134G>A p.S45N | Missense Mutation (SNP) | VAF 67/306 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs756881927; called by muse, mutect2, varscan2
- MICAL3 | c.3631G>A p.D1211N | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV71588215; called by muse, mutect2, varscan2
- MN1 | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.409); catalogued as rs774546408; called by muse, mutect2, varscan2
- NAA11 | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 95/243 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1177274678; called by muse, mutect2, varscan2
- NFATC2 | c.1778G>A p.G593D | Missense Mutation (SNP) | VAF 67/343 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101044805; called by muse, mutect2, varscan2
- NKG7 | c.179C>A p.T60N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as rs1190701600; called by muse, mutect2, varscan2
- NKIRAS2 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 132/331 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs147962346; called by muse, mutect2, varscan2
- OBSCN | c.10302T>G p.C3434W | Missense Mutation (SNP) | VAF 36/610 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs762721999, COSV52772355; called by muse, mutect2
- OCA2 | c.938C>T p.A313V | Missense Mutation (SNP) | VAF 107/345 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV62347194; called by muse, mutect2, varscan2
- OR4C11 | c.107C>A p.T36N | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100155221; called by muse, mutect2, varscan2
- OR4C6 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.093); catalogued as COSV58603388; called by muse, mutect2, varscan2
- OXR1 | c.143T>C p.I48T (on ENST00000442977 / NM_001198532.1; = p.I47T on NM_018002.3) | Missense Mutation (SNP) | VAF 89/354 reads (25%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs981752752; called by muse, mutect2, varscan2
- PDE1A | c.943G>T p.D315Y | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1445597045; called by muse, mutect2, varscan2
- PKD1L2 | c.1298C>A p.T433N | Missense Mutation (SNP) | VAF 43/300 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as rs1166649179; called by muse, mutect2, varscan2
- PLEKHH3 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV52217128; called by muse, mutect2, varscan2
- PPP3CA | c.1429G>A p.D477N | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100548076, COSV59921233; called by muse, mutect2, varscan2
- RCC1L | c.490G>T p.V164F | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV57319988; called by muse, mutect2, varscan2
- RHAG | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 121/368 reads (33%) | catalogued as COSV57702987; called by muse, mutect2, varscan2
- RINL | c.787del p.V263Sfs*95 (on ENST00000591812 / NM_001195833.2; = p.V149Sfs*95 on NM_198445.4) | Frame Shift Del (DEL) | VAF 140/540 reads (26%) | catalogued as COSV61574124; called by mutect2, pindel, varscan2
- SCAF8 | c.378G>T p.E126D | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV104425438; called by muse, mutect2
- SIGLEC6 | c.1246C>G p.P416A | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.069); catalogued as COSV100585614, COSV58436228; called by muse, mutect2, varscan2
- SORBS2 | c.1510G>C p.D504H | Missense Mutation (SNP) | VAF 85/232 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.28); catalogued as COSV52997981; called by muse, mutect2, varscan2
- STT3A | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as rs1382914261; called by muse, mutect2, varscan2
- STXBP1 | c.1342G>T p.V448L | Missense Mutation (SNP) | VAF 149/437 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.053); catalogued as COSV64814275; called by muse, mutect2, varscan2
- SUPT6H | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 93/323 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.053); catalogued as rs1288969489; called by muse, mutect2, varscan2
- TBX18 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.25); catalogued as COSV100858458, COSV63737895; called by muse, mutect2
- THSD7A | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.007); catalogued as rs1411237389; called by muse, mutect2, varscan2
- TTC28 | c.3359G>A p.R1120H | Missense Mutation (SNP) | VAF 15/257 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.889); catalogued as rs1045571342; called by muse, mutect2
- UBE3A | c.1995A>T p.L665F | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as CD1513604; called by muse, mutect2, varscan2
- USP20 | c.1239C>G p.S413R | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs759919130; called by muse, mutect2, varscan2
- XIRP2 | c.6059C>A p.S2020Y (on ENST00000628543; = p.S2195Y on NM_152381.6) | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV54714924; called by muse, mutect2, varscan2
- ZFR2 | c.1476C>A p.H492Q | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772968325, COSV53597042; called by muse, mutect2, varscan2
- ZNF696 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV57524479; called by muse, mutect2
- ABCB8 | c.1886A>T p.Q629L (on ENST00000297504 / NM_001282291.2; = p.Q612L on NM_007188.5) | Missense Mutation (SNP) | VAF 134/336 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- ABHD8 | c.960G>T p.K320N | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- ADAMTS12 | c.3758G>T p.G1253V | Missense Mutation (SNP) | VAF 83/498 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTS13 | c.101A>T p.Q34L | Missense Mutation (SNP) | VAF 91/255 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ADAMTS17 | c.1888+1del p.X630_splice | Splice Site (DEL) | VAF 118/508 reads (23%) | called by mutect2, pindel, varscan2
- AGMO | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- ANKRD33B | c.1302del p.T435Pfs*141 | Frame Shift Del (DEL) | VAF 91/275 reads (33%) | called by mutect2, pindel, varscan2
- ARHGAP17 | c.373G>T p.G125C | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ARHGEF28 | c.3920C>G p.S1307C | Missense Mutation (SNP) | VAF 45/153 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- ARRDC1 | c.224A>T p.D75V | Missense Mutation (SNP) | VAF 115/310 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ASXL3 | c.4787C>A p.T1596N | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP8B2 | c.2639_2641del p.F880del (on ENST00000672630; = p.F847del on NM_001367934.1 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 97/492 reads (20%) | called by mutect2, pindel, varscan2
- BHLHE22 | c.829G>T p.V277L | Missense Mutation (SNP) | VAF 148/574 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BIRC6 | c.7127A>T p.N2376I | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2
- BRIP1 | c.1223A>G p.Y408C | Missense Mutation (SNP) | VAF 51/267 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CABP2 | c.536C>G p.A179G | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); called by muse, mutect2
- CCDC61 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD79B | c.225C>A p.S75R | Missense Mutation (SNP) | VAF 221/476 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDYL | c.1577C>A p.P526H (on ENST00000328908 / NM_001368125.1; = p.P472H on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); called by muse, mutect2
- CFAP44 | c.4506A>T p.E1502D | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- CFAP69 | c.2731A>G p.I911V | Missense Mutation (SNP) | VAF 87/284 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CHRM2 | c.641dup p.S215Efs*32 | Frame Shift Ins (INS) | VAF 126/633 reads (20%) | called by mutect2, pindel, varscan2
- CLDN5 | c.538C>A p.L180I (on ENST00000618236 / NM_001363066.2; = p.L265I on NM_003277.4) | Missense Mutation (SNP) | VAF 115/485 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- CNMD | c.513C>G p.I171M | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- COBL | c.611del p.G204Efs*10 | Frame Shift Del (DEL) | VAF 71/396 reads (18%) | called by mutect2, pindel, varscan2
- COL15A1 | c.2428C>A p.H810N | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL4A1 | c.3636G>C p.M1212I | Missense Mutation (SNP) | VAF 124/482 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- COX10 | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 106/311 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- CRIM1 | c.722G>T p.C241F | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CSMD3 | c.8792T>A p.V2931D (on ENST00000297405 / NM_001363185.1; = p.V2762D on NM_052900.3) | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); called by muse, mutect2
- CSMD3 | c.6559C>A p.P2187T (on ENST00000297405 / NM_001363185.1; = p.P2083T on NM_052900.3) | Missense Mutation (SNP) | VAF 19/370 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CSN3 | c.194G>C p.R65P | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTCFL | c.606dup p.V203Cfs*8 | Frame Shift Ins (INS) | VAF 23/209 reads (11%) | called by mutect2, pindel, varscan2
- DAPK3 | c.354G>T p.Q118H | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DAZL | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 78/248 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DLGAP1 | c.2849G>C p.R950P | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH14 | c.5096C>G p.T1699S (on ENST00000445597; = p.T2104S on NM_001367479.1) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.24); called by muse, mutect2
- EEF1AKMT4-ECE2 | c.1605T>A p.Y535* | Nonsense Mutation (SNP) | VAF 54/135 reads (40%) | called by muse, mutect2, varscan2
- FAM189A1 | c.964T>G p.S322A | Missense Mutation (SNP) | VAF 19/263 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.035); called by muse, mutect2
- FAM189A1 | c.920C>A p.A307D | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.312); called by muse, mutect2
- FAM83H | c.1511G>T p.G504V | Missense Mutation (SNP) | VAF 27/334 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- FBN1 | c.5037G>T p.M1679I | Missense Mutation (SNP) | VAF 52/395 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- FLNB | c.1375G>T p.G459C | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FMNL2 | c.164A>G p.Y55C | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FRG2C | c.197C>A p.P66Q | Missense Mutation (SNP) | VAF 67/442 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); called by muse, varscan2
- FSIP2 | c.969C>A p.Y323* | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- GABRB3 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 29/228 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- GAREM2 | c.1969G>C p.V657L | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GATM | c.1121C>A p.A374D | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- GOLGA8J | c.964C>G p.L322V | Missense Mutation (SNP) | VAF 66/840 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- GPR26 | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRIN3B | c.2163C>A p.S721R | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- GRIP2 | c.809C>A p.S270Y (on ENST00000619221; = p.S173Y on NM_001080423.4) | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- GSX2 | c.37A>T p.K13* | Nonsense Mutation (SNP) | VAF 217/501 reads (43%) | called by muse, mutect2, varscan2
- HERC2 | c.9688G>T p.G3230* | Nonsense Mutation (SNP) | VAF 30/134 reads (22%) | called by muse, mutect2, varscan2
- HIP1 | c.1315G>C p.E439Q | Missense Mutation (SNP) | VAF 78/223 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- HOXA11 | c.423C>A p.D141E | Missense Mutation (SNP) | VAF 36/750 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.399); called by muse, mutect2
- HYOU1 | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 111/305 reads (36%) | called by muse, mutect2, varscan2
- IGSF1 | c.3889G>A p.D1297N | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- IL10RB | c.814C>T p.H272Y | Missense Mutation (SNP) | VAF 97/455 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IL2RA | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- INTS2 | c.509G>A p.S170N | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (1); PolyPhen probably damaging (0.943); called by muse, mutect2
- KIF5B | c.80A>G p.D27G | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- KNTC1 | c.4356C>T p.S1452= | Splice Region (SNP) | VAF 67/182 reads (37%) | called by muse, mutect2, varscan2
- LAMP1 | c.880G>T p.A294S | Missense Mutation (SNP) | VAF 69/264 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- LHB | c.232A>G p.T78A | Missense Mutation (SNP) | VAF 77/697 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- LINC00305 | n.764+1G>C | Splice Site (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- LRRTM1 | c.1201C>A p.Q401K | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- MBD3L3 | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 159/404 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- MBD3L3 | c.361G>T p.G121W | Missense Mutation (SNP) | VAF 158/405 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MPO | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MS4A2 | c.215G>T p.C72F | Missense Mutation (SNP) | VAF 72/368 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- MTO1 | c.1808T>A p.L603Q (on ENST00000370300 / NM_133645.3; = p.L578Q on NM_012123.4) | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- MTUS2 | c.1825C>A p.P609T | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MUC12 | c.16308C>A p.D5436E (on ENST00000379442; = p.D5293E on NM_001164462.1) | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated, low confidence (0.26); called by muse, mutect2, varscan2
- MUC5B | c.6901C>T p.P2301S | Missense Mutation (SNP) | VAF 129/555 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- MUC5B | c.15933C>A p.F5311L | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- MXRA5 | c.4163C>A p.P1388H | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- MYH13 | c.3930G>T p.Q1310H | Missense Mutation (SNP) | VAF 64/225 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- MYH13 | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- MYLK4 | c.362A>G p.H121R | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- MYOM2 | c.4081A>T p.T1361S | Missense Mutation (SNP) | VAF 112/347 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- NIPAL3 | c.800A>G p.Y267C | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NLRP7 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 64/417 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NOMO1 | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 50/299 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NRAP | c.1080G>T p.Q360H | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NRAP | c.484del p.E162Sfs*12 | Frame Shift Del (DEL) | VAF 17/134 reads (13%) | called by mutect2, pindel*, varscan2
- NRXN1 | c.654G>T p.E218D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- NSMF | c.1272G>T p.K424N (on ENST00000371475 / NM_001130969.3; = p.K422N on NM_015537.4) | Missense Mutation (SNP) | VAF 146/442 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NXNL2 | c.178C>G p.R60G | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- NYAP2 | c.336T>A p.S112R | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- OR10Q1 | c.711G>T p.E237D | Missense Mutation (SNP) | VAF 51/219 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- OR1C1 | c.214T>A p.C72S | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); called by muse, mutect2
- OR2B6 | c.872C>A p.T291K | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- OR2T3 | c.651G>T p.M217I | Missense Mutation (SNP) | VAF 70/289 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2W3 | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 76/280 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OR5I1 | c.703G>T p.G235W | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAK3 | c.1548G>T p.E516D (on ENST00000262836 / NM_001324328.2; = p.E501D on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/163 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- PARVG | c.584-6C>T | Splice Region (SNP) | VAF 51/182 reads (28%) | called by muse, mutect2, varscan2
- PCDHA11 | c.154C>A p.L52M | Missense Mutation (SNP) | VAF 74/447 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDILT | c.223T>C p.S75P | Missense Mutation (SNP) | VAF 75/243 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PEX2 | c.749G>T p.W250L | Missense Mutation (SNP) | VAF 47/227 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- PIP4K2A | c.269T>G p.F90C | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PKP2 | c.421T>A p.L141M | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- PLA2G2F | c.96del p.C33Vfs*12 | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | called by mutect2, pindel
- PLD1 | c.1382G>T p.W461L | Missense Mutation (SNP) | VAF 112/307 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- POTEC | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 82/391 reads (21%) | called by muse, mutect2, varscan2
- POTEF | c.1119C>G p.S373R | Missense Mutation (SNP) | VAF 65/400 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- PRDM6 | c.1761G>T p.E587D | Missense Mutation (SNP) | VAF 69/179 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PREPL | c.1762G>T p.V588F | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PREX1 | c.2007C>A p.Y669* | Nonsense Mutation (SNP) | VAF 56/196 reads (29%) | called by muse, mutect2, varscan2
- PREX1 | c.2006A>T p.Y669F | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTN | c.379C>A p.H127N | Missense Mutation (SNP) | VAF 101/443 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- PTPRM | c.1199G>C p.W400S | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PXDNL | c.4097G>T p.S1366I | Missense Mutation (SNP) | VAF 51/214 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PXDNL | c.3017del p.G1006Afs*25 | Frame Shift Del (DEL) | VAF 41/207 reads (20%) | called by mutect2, pindel, varscan2
- RP1L1 | c.6919G>T p.G2307C | Missense Mutation (SNP) | VAF 95/345 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- RPS7 | c.131A>G p.N44S | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.014); called by muse, mutect2
- RUSC1 | c.2629G>T p.V877L (on ENST00000368352 / NM_001105203.2; = p.V408L on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- SCAF8 | c.379A>C p.I127L | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); called by muse, mutect2
- SCN7A | c.3103C>A p.L1035I | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); called by muse, mutect2
- SIPA1L2 | c.4697C>T p.P1566L | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC30A2 | c.844dup p.Q282Pfs*62 | Frame Shift Ins (INS) | VAF 7/79 reads (9%) | called by mutect2, pindel
- SP6 | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ST8SIA3 | c.156G>A p.M52I | Missense Mutation (SNP) | VAF 65/173 reads (38%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- STAMBP | c.1194C>G p.H398Q | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SUGCT | c.860A>G p.N287S | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- SYNE1 | c.17305A>T p.S5769C (on ENST00000367255 / NM_182961.4; = p.S5698C on NM_033071.3) | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SYT3 | c.1648T>A p.W550R | Missense Mutation (SNP) | VAF 61/254 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAOK2 | c.1280A>G p.D427G | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- TBX2 | c.300G>T p.E100D | Missense Mutation (SNP) | VAF 144/368 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.028); called by muse, varscan2
- TCAIM | c.698G>T p.W233L | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TENM3 | c.1403C>G p.A468G | Missense Mutation (SNP) | VAF 102/264 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TLR4 | c.2452G>T p.G818C (on ENST00000355622 / NM_138554.5; = p.G778C on NM_003266.4) | Missense Mutation (SNP) | VAF 98/293 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TNK2 | c.2792G>A p.G931E | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.534); called by muse, mutect2
- TRAV1-1 | c.66G>T p.E22D | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIOBP | c.3310G>T p.E1104* | Nonsense Mutation (SNP) | VAF 67/210 reads (32%) | called by muse, mutect2, varscan2
- TRPC6 | c.505A>G p.I169V | Missense Mutation (SNP) | VAF 145/422 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TUBGCP5 | c.1372-7G>T | Splice Region (SNP) | VAF 20/268 reads (7%) | called by muse, mutect2
- TXLNG | c.498+1G>T p.X166_splice | Splice Site (SNP) | VAF 32/79 reads (41%) | called by muse, mutect2, varscan2
- UGT1A9 | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 67/241 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- UGT3A1 | c.1045G>T p.V349L | Missense Mutation (SNP) | VAF 77/351 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- USP9X | c.7639A>T p.R2547* | Nonsense Mutation (SNP) | VAF 50/119 reads (42%) | called by muse, mutect2, varscan2
- VLDLR | c.2554C>T p.H852Y | Missense Mutation (SNP) | VAF 15/328 reads (5%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.834); called by muse, mutect2
- VPS26B | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 38/248 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- VSIG10L | c.1190-1G>C p.X397_splice | Splice Site (SNP) | VAF 27/109 reads (25%) | called by muse, mutect2, varscan2
- VWA8 | c.792G>T p.R264S | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- WWP1 | c.120A>G p.I40M | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.756); called by muse, mutect2
- ZNF331 | c.1081G>T p.G361W | Missense Mutation (SNP) | VAF 80/287 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF431 | c.1275G>C p.E425D | Missense Mutation (SNP) | VAF 65/467 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- ZNF492 | c.1024T>A p.C342S | Missense Mutation (SNP) | VAF 67/356 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF577 | c.911G>T p.G304V | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ZNF587 | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 27/265 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- ZNF804A | c.1562G>C p.S521T | Missense Mutation (SNP) | VAF 6/123 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- AATK | c.4023C>T p.P1341= (on ENST00000326724 / NM_001080395.3; = p.P1238= on NM_004920.2) | Silent (SNP) | VAF 40/108 reads (37%) | catalogued as rs770351918; called by muse, mutect2, varscan2
- ADAMTS16 | c.2658A>T p.G886= | Silent (SNP) | VAF 63/281 reads (22%) | catalogued as COSV57006002; called by muse, mutect2, varscan2
- ALDH4A1 | c.1503C>T p.A501= | Silent (SNP) | VAF 21/228 reads (9%) | catalogued as rs376695697; called by muse, mutect2, varscan2
- AMER3 | c.2013C>A p.P671= | Silent (SNP) | VAF 57/184 reads (31%) | called by muse, mutect2, varscan2
- ARHGAP32 | c.1614C>T p.A538= (on ENST00000310343 / NM_001378025.1; = p.A189= on NM_014715.4) | Silent (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- ATOH8 | c.522C>G p.P174= | Silent (SNP) | VAF 37/150 reads (25%) | catalogued as rs760869571; called by muse, mutect2, varscan2
- CELF3 | c.150T>C p.C50= | Silent (SNP) | VAF 69/301 reads (23%) | catalogued as COSV51883556; called by muse, mutect2, varscan2
- COL13A1 | c.1803C>G p.G601= (on ENST00000398978 / NM_001130103.2; = p.G529= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/159 reads (21%) | called by muse, mutect2, varscan2
- CPS1 | c.756C>A p.T252= | Silent (SNP) | VAF 53/159 reads (33%) | catalogued as COSV99243737; called by muse, mutect2, varscan2
- CPS1 | c.2148T>C p.N716= | Silent (SNP) | VAF 18/156 reads (12%) | catalogued as CM063920; called by muse, mutect2, varscan2
- CTNNA2 | c.2664C>G p.T888= (on ENST00000402739 / NM_001282597.3; = p.T840= on NM_004389.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/149 reads (31%) | called by muse, mutect2, varscan2
- DCT | c.477C>T p.T159= | Silent (SNP) | VAF 134/478 reads (28%) | called by muse, mutect2, varscan2
- DLEU7 | c.585A>G p.S195= | Silent (SNP) | VAF 53/152 reads (35%) | called by muse, mutect2, varscan2
- DNAH5 | c.7458C>T p.F2486= | Silent (SNP) | VAF 20/316 reads (6%) | catalogued as rs1554058794, COSV54223844; ClinVar: likely benign; called by muse, mutect2
- DOCK2 | c.1110C>G p.S370= | Silent (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- EPHA10 | c.1953T>A p.L651= | Silent (SNP) | VAF 42/456 reads (9%) | called by muse, mutect2
- FAM47B | c.1257G>T p.R419= | Silent (SNP) | VAF 89/208 reads (43%) | called by muse, mutect2, varscan2
- FAT2 | c.6222C>A p.P2074= | Silent (SNP) | VAF 53/150 reads (35%) | called by muse, mutect2, varscan2
- FAT3 | c.9573G>A p.Q3191= | Silent (SNP) | VAF 69/255 reads (27%) | catalogued as rs760693512; called by muse, mutect2, varscan2
- FLNB | c.5379C>T p.V1793= | Silent (SNP) | VAF 17/256 reads (7%) | called by muse, mutect2
- GAB4 | c.957C>A p.T319= | Silent (SNP) | VAF 46/227 reads (20%) | called by muse, mutect2, varscan2
- GCH1 | c.300G>A p.S100= | Silent (SNP) | VAF 29/307 reads (9%) | catalogued as rs777068790; called by muse, mutect2
- GLB1L3 | c.1242G>A p.P414= | Silent (SNP) | VAF 9/252 reads (4%) | catalogued as rs1236064997, COSV68392493; called by muse, mutect2
- HHIPL2 | c.645G>T p.G215= | Silent (SNP) | VAF 120/400 reads (30%) | called by muse, mutect2, varscan2
- IQCA1 | c.1728G>A p.P576= | Silent (SNP) | VAF 44/151 reads (29%) | catalogued as rs374874665; called by muse, mutect2, varscan2
- IRS2 | c.1230C>G p.G410= | Silent (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- ITGAE | c.2067C>T p.T689= | Silent (SNP) | VAF 42/139 reads (30%) | catalogued as rs1276873213; called by muse, mutect2, varscan2
- KIF1C | c.3150C>G p.P1050= | Silent (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- LIPG | c.396G>A p.T132= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as rs376564046; called by muse, mutect2
- MAFG | c.216G>T p.R72= | Silent (SNP) | VAF 99/262 reads (38%) | called by muse, mutect2, varscan2
- MEGF8 | c.3864A>T p.P1288= (on ENST00000251268 / NM_001271938.2; = p.P1221= on NM_001410.3) | Silent (SNP) | VAF 22/242 reads (9%) | catalogued as rs1319773817, COSV52104553; called by muse, mutect2
- MRPL3 | c.513G>T p.P171= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as COSV53916068; called by muse, mutect2, varscan2
- NHSL2 | c.159C>G p.S53= (on ENST00000510661; = p.S419= on NM_001013627.2) | Silent (SNP) | VAF 41/82 reads (50%) | called by muse, mutect2, varscan2
- NOMO1 | c.183G>A p.K61= | Silent (SNP) | VAF 48/294 reads (16%) | called by muse, mutect2, varscan2
- NTN5 | c.1242C>T p.A414= | Silent (SNP) | VAF 18/220 reads (8%) | called by muse, mutect2
- OBSL1 | c.3060G>T p.V1020= | Silent (SNP) | VAF 84/341 reads (25%) | called by muse, mutect2, varscan2
- OLFML1 | c.612C>A p.P204= | Silent (SNP) | VAF 60/251 reads (24%) | called by muse, mutect2, varscan2
- OR10D3 | c.129G>T p.V43= | Silent (SNP) | VAF 121/409 reads (30%) | called by muse, mutect2, varscan2
- OR14C36 | c.381A>T p.P127= | Silent (SNP) | VAF 12/169 reads (7%) | called by muse, mutect2
- OXGR1 | c.120T>C p.Y40= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as rs1476293302; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.435C>T p.D145= (on ENST00000259318 / NM_001136562.3; = p.D376= on NM_007203.5) | Silent (SNP) | VAF 41/118 reads (35%) | called by muse, mutect2, varscan2
- PAXIP1 | c.2682G>A p.A894= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs762210325; called by muse, mutect2, varscan2
- PAXX | c.447G>T p.P149= | Silent (SNP) | VAF 38/102 reads (37%) | called by muse, mutect2, varscan2
- PCDHA1 | c.1863G>T p.P621= | Silent (SNP) | VAF 141/353 reads (40%) | catalogued as rs782127255, COSV65375111; called by muse, mutect2, varscan2
- PEG3 | c.2247G>T p.A749= | Silent (SNP) | VAF 37/152 reads (24%) | catalogued as COSV55636264; called by muse, mutect2, varscan2
- PIEZO2 | c.3486C>T p.I1162= | Silent (SNP) | VAF 60/239 reads (25%) | catalogued as rs370577821; called by muse, mutect2, varscan2
- POLR1A | c.1725G>T p.L575= | Silent (SNP) | VAF 28/198 reads (14%) | called by muse, mutect2, varscan2
- POM121L2 | c.1398C>T p.I466= | Silent (SNP) | VAF 20/275 reads (7%) | called by muse, mutect2
- PROM2 | c.312G>T p.A104= | Silent (SNP) | VAF 111/385 reads (29%) | catalogued as COSV100469003; called by muse, mutect2, varscan2
- RELN | c.2685C>G p.G895= | Silent (SNP) | VAF 112/316 reads (35%) | called by muse, mutect2, varscan2
- RGS5 | c.162G>T p.S54= | Silent (SNP) | VAF 74/273 reads (27%) | catalogued as COSV58352302; called by muse, mutect2, varscan2
- RNFT1 | c.639A>T p.A213= | Silent (SNP) | VAF 47/118 reads (40%) | called by muse, mutect2, varscan2
- ROR1 | c.1749G>A p.V583= | Silent (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2, varscan2
- RUSC1 | c.2628A>C p.T876= (on ENST00000368352 / NM_001105203.2; = p.T407= on NM_014328.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 43/187 reads (23%) | called by muse, mutect2, varscan2
- SCN7A | c.3102C>A p.P1034= | Silent (SNP) | VAF 14/154 reads (9%) | catalogued as COSV69274731; called by muse, mutect2
- SDF2L1 | c.522G>A p.T174= | Silent (SNP) | VAF 62/571 reads (11%) | catalogued as rs756431815, COSV99963604; called by muse, mutect2, varscan2
- SGK2 | c.660G>C p.L220= | Silent (SNP) | VAF 43/184 reads (23%) | called by muse, varscan2
- SLC6A4 | c.1503G>T p.V501= | Silent (SNP) | VAF 71/270 reads (26%) | called by muse, mutect2, varscan2
- SLCO2B1 | c.864C>A p.A288= | Silent (SNP) | VAF 32/150 reads (21%) | called by muse, mutect2, varscan2
- TECPR1 | c.36C>T p.F12= | Silent (SNP) | VAF 26/255 reads (10%) | catalogued as rs781388045, COSV65783157; called by muse, mutect2, varscan2
- TERT | c.2280G>A p.K760= | Silent (SNP) | VAF 40/596 reads (7%) | called by muse, mutect2
- TFIP11 | c.1806C>A p.G602= | Silent (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- TIMD4 | c.129A>G p.S43= | Silent (SNP) | VAF 18/176 reads (10%) | catalogued as rs778983337; called by muse, mutect2
- TMEM43 | c.1074G>A p.S358= | Silent (SNP) | VAF 20/366 reads (5%) | catalogued as rs377104916; ClinVar: likely benign; called by muse, mutect2
- TNK2 | c.2793G>A p.G931= | Silent (SNP) | VAF 42/94 reads (45%) | catalogued as rs1300731153; called by muse, mutect2
- TNKS2 | c.3066C>T p.N1022= | Silent (SNP) | VAF 7/129 reads (5%) | called by muse, mutect2
- TTLL1 | c.123G>A p.V41= | Silent (SNP) | VAF 62/212 reads (29%) | called by muse, mutect2, varscan2
- UBR3 | c.4326C>A p.G1442= | Silent (SNP) | VAF 16/255 reads (6%) | catalogued as rs757525563; called by muse, mutect2
- USH2A | c.13422C>A p.I4474= | Silent (SNP) | VAF 97/376 reads (26%) | called by muse, mutect2, varscan2
- WNT10A | c.837G>A p.V279= | Silent (SNP) | VAF 58/319 reads (18%) | called by muse, mutect2, varscan2
- ZFR2 | c.1477C>A p.R493= | Silent (SNP) | VAF 67/159 reads (42%) | called by muse, mutect2, varscan2
- ZNF516 | c.1119G>T p.A373= | Silent (SNP) | VAF 139/386 reads (36%) | called by muse, mutect2, varscan2
- ZNF683 | c.1374C>A p.T458= (on ENST00000403843; = p.T438= on NM_173574.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/237 reads (11%) | called by muse, mutect2, varscan2
- ZSCAN5C | c.555C>A p.T185= | Silent (SNP) | VAF 56/196 reads (29%) | called by muse, mutect2
- AC011330.1 | n.999C>T | RNA (SNP) | VAF 24/203 reads (12%) | called by mutect2, varscan2
- AC078880.2 | n.293C>T | RNA (SNP) | VAF 142/312 reads (46%) | called by muse, mutect2, varscan2
- ACTR3BP2 | n.818A>T | RNA (SNP) | VAF 45/164 reads (27%) | called by muse, mutect2, varscan2
- ADAR | c.-938G>T | 5'UTR (SNP) | VAF 73/220 reads (33%) | called by muse, mutect2, varscan2
- BAIAP2L1 | c.-21G>T | 5'UTR (SNP) | VAF 55/248 reads (22%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.*18C>A | 3'UTR (SNP) | VAF 143/386 reads (37%) | called by muse, mutect2, varscan2
- CCDC150 | c.1866+873G>C | Intron (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- CES5A | c.-9G>T | 5'UTR (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2
- COL9A3 | c.-9C>T | 5'UTR (SNP) | VAF 37/138 reads (27%) | catalogued as rs1441787996; called by muse, mutect2, varscan2
- COPS2 | chr15:49156003 G>A | 5'Flank (SNP) | VAF 20/149 reads (13%) | called by muse, mutect2, varscan2
- CSF2RA | c.647-25G>T | Intron (SNP) | VAF 104/364 reads (29%) | called by muse, mutect2, varscan2
- CSH2 | c.456+18G>T | Intron (SNP) | VAF 171/676 reads (25%) | called by muse, mutect2, varscan2
- DCX | c.-22-602G>T | Intron (SNP) | VAF 21/56 reads (38%) | catalogued as rs750545232, COSV100576575; called by muse, mutect2, varscan2
- DECR2 | c.201+211C>T | Intron (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- ETDB | chrX:135123377 G>T | 5'Flank (SNP) | VAF 74/177 reads (42%) | called by muse, mutect2, varscan2
- GIMAP6 | c.86-97T>C | Intron (SNP) | VAF 34/86 reads (40%) | called by muse, mutect2, varscan2
- GLRA2 | c.68+1002C>T | Intron (SNP) | VAF 18/144 reads (13%) | called by muse, mutect2, varscan2
- GNG12 | c.-4G>T | 5'UTR (SNP) | VAF 31/90 reads (34%) | catalogued as COSV100921364; called by muse, mutect2, varscan2
- IGLV8-61 | c.-17G>T | 5'UTR (SNP) | VAF 13/121 reads (11%) | called by muse, mutect2, varscan2
- IPO9 | c.*30C>T | 3'UTR (SNP) | VAF 111/461 reads (24%) | called by muse, mutect2, varscan2
- KCNMA1 | c.2484+1738C>T | Intron (SNP) | VAF 18/163 reads (11%) | called by muse, mutect2, varscan2
- LDLRAD3 | c.454+3467G>T | Intron (SNP) | VAF 8/37 reads (22%) | called by mutect2, varscan2
- LRCH3 | c.2209-2852T>C | Intron (SNP) | VAF 29/360 reads (8%) | called by muse, mutect2
- MAPK14 | c.763-2314C>T | Intron (SNP) | VAF 22/272 reads (8%) | called by muse, mutect2
- MICALL2 | c.*150C>G | 3'UTR (SNP) | VAF 68/379 reads (18%) | catalogued as COSV52514703; called by muse, mutect2, varscan2
- MPDZ | c.4003+64A>G | Intron (SNP) | VAF 59/147 reads (40%) | called by muse, mutect2, varscan2
- MROH8 | c.109+2791C>A | Intron (SNP) | VAF 39/131 reads (30%) | called by muse, mutect2, varscan2
- NXNL1 | c.-30C>T | 5'UTR (SNP) | VAF 29/142 reads (20%) | catalogued as rs1307534272; called by muse, mutect2, varscan2
- OBSCN | c.11660-1175G>T | Intron (SNP) | VAF 117/483 reads (24%) | called by muse, mutect2, varscan2
- PARVG | c.*9G>A | 3'UTR (SNP) | VAF 60/282 reads (21%) | called by muse, mutect2, varscan2
- PARVG | c.*10C>G | 3'UTR (SNP) | VAF 61/279 reads (22%) | called by muse, mutect2, varscan2
- PPP1R2P1 | n.427C>A | RNA (SNP) | VAF 70/185 reads (38%) | called by muse, mutect2, varscan2
- PRPF18 | c.66+4750G>A | Intron (SNP) | VAF 7/187 reads (4%) | catalogued as rs1480820270; called by muse, mutect2
- RNF170 | c.-8+18C>A | Intron (SNP) | VAF 19/316 reads (6%) | called by muse, mutect2
- RPS17 | c.*187A>G | 3'UTR (SNP) | VAF 102/380 reads (27%) | called by muse, mutect2
- RUFY2 | c.-71C>T | 5'UTR (SNP) | VAF 20/139 reads (14%) | called by muse, mutect2, varscan2
- RUSC1 | c.-87+34T>A | Intron (SNP) | VAF 20/120 reads (17%) | called by muse, mutect2, varscan2
- SATB2 | c.347-15905G>A | Intron (SNP) | VAF 11/88 reads (13%) | catalogued as rs779273222; called by muse, mutect2, varscan2
- SSPOP | n.3157C>T | RNA (SNP) | VAF 106/566 reads (19%) | catalogued as COSV100022101; called by muse, mutect2, varscan2
- ST13P4 | n.192C>A | RNA (SNP) | VAF 138/391 reads (35%) | called by muse, mutect2, varscan2
- STK11IP | c.945+60T>A | Intron (SNP) | VAF 93/358 reads (26%) | called by muse, mutect2, varscan2
- TMC6 | c.2278-44C>T | Intron (SNP) | VAF 105/369 reads (28%) | called by muse, mutect2, varscan2
- TOX2 | c.907-883C>A | Intron (SNP) | VAF 20/208 reads (10%) | called by muse, mutect2
- TSPY8 | c.-7C>A | 5'UTR (SNP) | VAF 51/275 reads (19%) | called by muse, mutect2, varscan2
- UTP23 | chr8:116779539 A>T | 3'Flank (SNP) | VAF 13/234 reads (6%) | called by muse, mutect2
- Unknown | chr17:43379238 C>T | IGR (SNP) | VAF 49/175 reads (28%) | catalogued as rs1436769383; called by muse, mutect2, varscan2
- VPS37C | c.348+16G>C | Intron (SNP) | VAF 102/465 reads (22%) | called by muse, mutect2, varscan2
